Somatic mutation profile of tumor specimen C3N-02636-02 (aliquot CPT0182150006) from CPTAC case C3N-02636, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 72.7 years (26,559 days).
Specimen C3N-02636-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4202dab7-3e6b-4683-a8d7-7cf6e61bb45b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02636-31 (Blood Derived Normal), aliquot CPT0182200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/159b1605-089d-4d05-a594-8745462f5cba

The open-access MAF lists 84 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Frame Shift Del 5, Nonsense Mutation 3, 5'UTR 3, Intron 2, Frame Shift Ins 2, 3'UTR 2, Splice Region 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 82/394 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 56/193 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372272045, COSV55846581, COSV55847676; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 84/252 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFAP1L2 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767778015, COSV58412347; called by muse, mutect2, varscan2
- CIB1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs369465701; called by muse, mutect2, varscan2
- DOCK5 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 100/282 reads (35%) | catalogued as rs778453756; called by muse, mutect2, varscan2
- FAM135A | c.2396A>G p.N799S (on ENST00000370479 / NM_001351599.1; = p.N586S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs762578706; called by muse, mutect2, varscan2
- IGHA1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 119/826 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs370272298; called by muse, mutect2, varscan2
- INO80 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV62737155; called by muse, mutect2
- ISOC2 | c.484G>A p.E162K (on ENST00000425675 / NM_001136201.2; = p.E178K on NM_024710.3) | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs757745171, COSV50034874; called by muse, mutect2, varscan2
- MLST8 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs375231338; called by muse, mutect2, varscan2
- MUC12 | c.9781A>G p.T3261A (on ENST00000379442; = p.T3118A on NM_001164462.1) | Missense Mutation (SNP) | VAF 98/2792 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV65182323; called by muse, mutect2
- NEFM | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 157/627 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV55334238; called by muse, mutect2, varscan2
- OTOA | c.2279C>T p.T760M (on ENST00000286149; = p.T746M on NM_144672.4) | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.12); catalogued as rs768161528, COSV53753464; called by muse, mutect2
- PABPC4 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs754646844; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1728insT p.R577Efs*25 (on ENST00000521381 / NM_181523.3; = p.R307Efs*25 on NM_181504.4) | Frame Shift Ins (INS) | VAF 58/117 reads (50%) | catalogued as COSV99141055; called by mutect2, pindel, varscan2
- PKD1L3 | c.2552del p.G851Efs*27 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | catalogued as COSV100626322; called by mutect2, pindel, varscan2
- PLXNB3 | c.4015C>T p.R1339C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781808141, COSV62802098; called by muse, mutect2, varscan2
- RIPK4 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 139/473 reads (29%) | catalogued as rs1465463078, COSV60192347; called by muse, mutect2, varscan2
- RNF17 | c.2939G>T p.R980L | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV99693307; called by muse, mutect2, varscan2
- SCRIB | c.4417G>A p.V1473M | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs782501621; called by muse, mutect2, varscan2
- SP3 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 91/354 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs952191257; called by muse, mutect2, varscan2
- SYCP1 | c.1884del p.G629Vfs*8 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs762984894, COSV65697419; called by mutect2, varscan2
- TRMT44 | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs772101499; called by muse, mutect2, varscan2
- ZNRF3 | c.958G>A p.V320M (on ENST00000544604 / NM_001206998.2; = p.V220M on NM_032173.3) | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60432823; called by muse, varscan2
- ADARB1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARID1A | c.3977_3983del p.P1326Rfs*153 | Frame Shift Del (DEL) | VAF 61/279 reads (22%) | called by pindel, varscan2
- ATP11B | c.2844A>C p.R948= | Splice Region (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- ATP2B1 | c.379dup p.Y127Lfs*8 | Frame Shift Ins (INS) | VAF 35/155 reads (23%) | called by mutect2, pindel, varscan2
- CACNA1I | c.6322G>A p.E2108K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CEMIP2 | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX31 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM9A | c.257A>T p.N86I | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- FBF1 | c.1156C>A p.P386T (on ENST00000586717; = p.P400T on NM_001319193.1) | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- FN1 | c.2376G>T p.Q792H | Missense Mutation (SNP) | VAF 82/334 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- GPRASP2 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 121/414 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITM2B | c.417T>G p.D139E | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- LANCL3 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 158/486 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MAB21L2 | c.395_404del p.F132Wfs*17 | Frame Shift Del (DEL) | VAF 73/273 reads (27%) | called by mutect2, pindel, varscan2
- MMEL1 | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MUC12 | c.1709G>A p.S570N (on ENST00000379442; = p.S427N on NM_001164462.1) | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- OR1D2 | c.590_591del p.T197Sfs*36 | Frame Shift Del (DEL) | VAF 50/198 reads (25%) | called by pindel, varscan2
- OR4K15 | c.542C>A p.T181N (on ENST00000305051; = p.T157N on NM_001005486.1) | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PLA2G2F | c.462C>A p.C154* | Nonsense Mutation (SNP) | VAF 105/262 reads (40%) | called by muse, mutect2, varscan2
- RB1CC1 | c.1890G>T p.Q630H | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ROCK2 | c.698T>G p.F233C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH2B1 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- SIL1 | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 354/536 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- SNX33 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2
- SPOCD1 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1L | c.5114G>T p.C1705F | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TAF1L | c.1997C>G p.A666G | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- TKTL2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZFYVE16 | c.4601T>C p.I1534T | Missense Mutation (SNP) | VAF 88/129 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ZIM2 | c.974A>T p.N325I | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS7 | c.1044A>G p.A348= | Silent (SNP) | VAF 101/319 reads (32%) | catalogued as rs1227999774; called by muse, mutect2, varscan2
- AMER2 | c.870C>T p.P290= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs946327141; called by muse, mutect2, varscan2
- ATP1A1 | c.978T>C p.G326= | Silent (SNP) | VAF 89/243 reads (37%) | called by muse, mutect2, varscan2
- CDH11 | c.1662C>T p.Y554= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs200486624, COSV99217300; called by muse, mutect2, varscan2
- CDHR1 | c.1149C>T p.T383= | Silent (SNP) | VAF 95/325 reads (29%) | catalogued as rs773136967; called by muse, mutect2, varscan2
- CSF2RA | c.768C>T p.D256= | Silent (SNP) | VAF 73/249 reads (29%) | catalogued as rs764658015; called by muse, mutect2, varscan2
- CT55 | c.441G>A p.K147= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as rs782177222; called by muse, mutect2, varscan2
- DMD | c.10824C>T p.G3608= | Silent (SNP) | VAF 152/513 reads (30%) | called by muse, mutect2, varscan2
- DSC3 | c.1435C>A p.R479= | Silent (SNP) | VAF 118/387 reads (30%) | catalogued as COSV64572400; called by muse, mutect2, varscan2
- FER1L6 | c.4047G>A p.P1349= | Silent (SNP) | VAF 39/236 reads (17%) | catalogued as rs376439710; called by muse, mutect2, varscan2
- GFUS | c.459G>A p.Q153= | Silent (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- INTS6L | c.2097A>G p.S699= | Silent (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- IRAG1 | c.1056G>A p.A352= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as rs371801567; called by muse, mutect2, varscan2
- KLK7 | c.531G>T p.T177= | Silent (SNP) | VAF 51/191 reads (27%) | called by muse, mutect2, varscan2
- NELL2 | c.2151G>A p.Q717= | Silent (SNP) | VAF 30/104 reads (29%) | called by muse, varscan2
- OR6K3 | c.693G>T p.L231= (on ENST00000368146; = p.L215= on NM_001005327.2) | Silent (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- POLDIP2 | c.693C>T p.S231= | Silent (SNP) | VAF 97/373 reads (26%) | catalogued as rs374185956; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.873G>A p.T291= (on ENST00000352766; = p.T168= on NM_181334.5) | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as rs769321323; called by muse, mutect2, varscan2
- TLX3 | c.120C>T p.G40= | Silent (SNP) | VAF 98/286 reads (34%) | called by muse, mutect2, varscan2
- AC011487.2 | n.1043G>A | RNA (SNP) | VAF 83/304 reads (27%) | catalogued as rs539589545; called by muse, mutect2, varscan2
- CASZ1 | c.2680+143G>T | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- CD70 | chr19:6583431 G>A | 3'Flank (SNP) | VAF 13/54 reads (24%) | catalogued as rs781481040, COSV104368712; called by muse, mutect2, varscan2
- GALT | c.253-94T>G | Intron (SNP) | VAF 159/423 reads (38%) | called by muse, mutect2, varscan2
- IL16 | c.-140G>T | 5'UTR (SNP) | VAF 92/329 reads (28%) | called by muse, mutect2, varscan2
- IP6K2 | c.-44G>T | 5'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- PARP15 | c.-10C>T | 5'UTR (SNP) | VAF 121/369 reads (33%) | called by muse, mutect2, varscan2
- PAWR | c.*7480G>A | 3'UTR (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- TPM4 | c.*204G>A | 3'UTR (SNP) | VAF 10/212 reads (5%) | catalogued as COSV56289956; called by muse, mutect2
